Somatic mutation profile of tumor specimen ALCH-B0H9-TTP1-A (aliquot ALCH-B0H9-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0H9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,642 days).
Specimen ALCH-B0H9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54332687-7b67-4171-823a-a9aebc226197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0H9-NB1-A (Blood Derived Normal), aliquot ALCH-B0H9-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeca74f0-2b04-4cd8-a960-78f514cf1a22

The open-access MAF lists 69 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Intron 7, Nonsense Mutation 5, 3'UTR 3, 5'UTR 3, Splice Region 1, In Frame Del 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 41/776 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1382100120, CM103531, COSV55591915; called by muse, mutect2
- ARID1A | c.5122C>T p.Q1708* | Nonsense Mutation (SNP) | VAF 14/344 reads (4%) | catalogued as COSV61380903; called by muse, mutect2
- C2orf88 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 30/648 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs1308166608; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 12/95 reads (13%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- FSIP2 | c.17308G>A p.D5770N | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1479991993, COSV100555547; called by muse, mutect2
- HAVCR2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 64/731 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747172640; called by muse, mutect2
- JAG1 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 117/1069 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs749076521; called by muse, mutect2, varscan2
- KCNG1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.684); catalogued as COSV65369690; called by muse, mutect2, varscan2
- KNDC1 | c.4259G>A p.R1420Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1026659510; called by muse, mutect2
- KRT12 | c.497C>G p.T166S | Missense Mutation (SNP) | VAF 82/765 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1362054659; called by muse, mutect2, varscan2
- MPHOSPH9 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 21/608 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1297206932, COSV56624972; called by muse, mutect2
- PCDHGC5 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779739693, COSV52755637; called by muse, mutect2
- PCSK5 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65084686; called by muse, mutect2, varscan2
- RIPOR3 | c.2771T>C p.M924T | Missense Mutation (SNP) | VAF 87/684 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs1276831474; called by muse, mutect2, varscan2
- SLC12A6 | c.2230C>T p.R744* (on ENST00000354181 / NM_001365088.1; = p.R693* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 60/635 reads (9%) | catalogued as rs751184319; called by muse, mutect2
- TSPAN2 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 52/486 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65690693; called by muse, mutect2, varscan2
- ZCCHC14 | c.1723C>T p.L575F (on ENST00000268616; = p.L712F on NM_015144.3) | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.922); catalogued as rs1158076987; called by muse, varscan2
- ZCCHC14 | c.1086C>G p.C362W (on ENST00000268616; = p.C499W on NM_015144.3) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV51891357; called by muse, varscan2
- ZFYVE21 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1173957416; called by muse, mutect2, varscan2
- ZNF107 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as rs754879638, COSV61329037; called by muse, mutect2, varscan2
- ABCC10 | c.1737C>G p.N579K (on ENST00000372530 / NM_001198934.2; = p.N536K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- CNTNAP4 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 15/377 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.697); called by muse, mutect2
- FAXC | c.1214A>G p.H405R | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); called by muse, mutect2
- FRMPD2 | c.1856A>G p.D619G | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- HHLA1 | c.1520G>T p.C507F | Missense Mutation (SNP) | VAF 132/762 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2B | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IER5 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- LYVE1 | c.488T>G p.I163S | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.345T>G p.Y115* | Nonsense Mutation (SNP) | VAF 39/323 reads (12%) | called by muse, mutect2, varscan2
- OSBPL9 | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RY6 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCM1 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEX5L | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- PGAM2 | c.595+8C>A | Splice Region (SNP) | VAF 18/406 reads (4%) | called by muse, mutect2
- POP5 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 67/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.4156C>T p.Q1386* | Nonsense Mutation (SNP) | VAF 201/1517 reads (13%) | called by muse, mutect2, varscan2
- SLC30A7 | c.857T>A p.L286* | Nonsense Mutation (SNP) | VAF 40/208 reads (19%) | called by muse, varscan2
- WBP2 | c.610A>T p.M204L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF268 | c.1227del p.H410Ifs*60 | Frame Shift Del (DEL) | VAF 25/232 reads (11%) | called by mutect2, pindel, varscan2
- ZNF91 | c.3470C>A p.T1157N | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ADAM17 | c.1323T>C p.S441= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- ADAMTS1 | c.1497C>T p.C499= | Silent (SNP) | VAF 90/686 reads (13%) | called by muse, mutect2, varscan2
- ADGRE1 | c.2118C>T p.R706= | Silent (SNP) | VAF 47/970 reads (5%) | called by muse, mutect2
- CLDND1 | c.54T>C p.I18= | Silent (SNP) | VAF 77/515 reads (15%) | called by muse, mutect2, varscan2
- EDEM2 | c.834C>T p.A278= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- FLG | c.3036T>C p.T1012= | Silent (SNP) | VAF 43/1056 reads (4%) | catalogued as COSV64246394; called by muse, mutect2
- LTBP1 | c.1056C>T p.I352= (on ENST00000404816 / NM_206943.4; = p.I26= on NM_000627.4) | Silent (SNP) | VAF 58/890 reads (7%) | catalogued as rs1295831517, COSV100616660; called by muse, mutect2
- NDUFAB1 | c.207C>T p.S69= | Silent (SNP) | VAF 36/518 reads (7%) | catalogued as rs764029297; called by muse, mutect2
- PKHD1L1 | c.2572T>C p.L858= | Silent (SNP) | VAF 54/430 reads (13%) | called by muse, mutect2, varscan2
- PSD2 | c.148C>A p.R50= | Silent (SNP) | VAF 53/786 reads (7%) | called by muse, mutect2
- RCAN1 | c.270C>T p.L90= | Silent (SNP) | VAF 49/340 reads (14%) | catalogued as COSV58249671, COSV58250452; called by muse, mutect2, varscan2
- SLC6A3 | c.360C>T p.L120= | Silent (SNP) | VAF 48/581 reads (8%) | catalogued as rs148447720; ClinVar: likely benign; called by muse, mutect2
- ZCCHC14 | c.1452C>T p.S484= (on ENST00000268616; = p.S621= on NM_015144.3) | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- ZPLD1 | c.1104C>T p.N368= (on ENST00000466937 / NM_001329788.1; = p.N384= on NM_175056.2) | Silent (SNP) | VAF 10/305 reads (3%) | catalogued as rs887317312; called by muse, mutect2
- AKR1C2 | c.*40G>A | 3'UTR (SNP) | VAF 33/428 reads (8%) | catalogued as rs1182047832; called by muse, mutect2, varscan2
- ARID1B | c.3511+2031del | Intron (DEL) | VAF 64/540 reads (12%) | called by mutect2, varscan2
- ASIC2 | c.556-179520G>T | Intron (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- CACNA1G | c.-11C>A | 5'UTR (SNP) | VAF 45/352 reads (13%) | called by muse, mutect2, varscan2
- DHODH | c.435-51T>G | Intron (SNP) | VAF 90/732 reads (12%) | called by muse, mutect2, varscan2
- HINT2 | c.81+44G>A | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- IRF6 | c.*48T>A | 3'UTR (SNP) | VAF 35/284 reads (12%) | called by muse, mutect2, varscan2
- KIF5A | c.1569+13C>G | Intron (SNP) | VAF 75/750 reads (10%) | called by muse, mutect2
- OSBPL2 | chr20:62232954 G>A | 5'Flank (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- PARP1 | c.286+124G>T | Intron (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- PARP6 | c.-24G>T | 5'UTR (SNP) | VAF 24/415 reads (6%) | called by muse, mutect2
- PPP6R1 | c.-6-80C>T | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101336932; called by muse, mutect2, varscan2
- TMEM160 | c.-1C>T | 5'UTR (SNP) | VAF 23/181 reads (13%) | catalogued as rs758390676; called by muse, mutect2, varscan2
- TUBB8P7 | n.1577G>A | RNA (SNP) | VAF 94/1002 reads (9%) | catalogued as rs771148691; called by muse, mutect2
- VGF | c.*137C>T | 3'UTR (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
